Somatic mutation profile of tumor specimen TCGA-SW-A7EA-01A (aliquot TCGA-SW-A7EA-01A-12D-A34U-08) from TCGA case TCGA-SW-A7EA, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IB; Tumor grade: GX; Age at diagnosis: 61.0 years (22,294 days).
Specimen TCGA-SW-A7EA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5617516d-4fd2-45fa-867d-66a80b69d244.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SW-A7EA-10A (Blood Derived Normal), aliquot TCGA-SW-A7EA-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d9aac3c-3e49-49b1-9cb3-dc05ad8d8e05

The open-access MAF lists 724 somatic variants for this specimen: 536 protein-altering or splice-affecting, 166 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 363, Silent 166, Frame Shift Del 95, Frame Shift Ins 31, Nonsense Mutation 26, Intron 10, Splice Site 8, In Frame Del 6, RNA 6, Splice Region 5, 3'Flank 3, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTBD11 | c.3008A>T p.K1003M (on ENST00000280758 / NM_001018072.2; = p.K540M on NM_001017523.2) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV55025836, COSV55028973, COSV55038748; called by muse, mutect2
- C19orf12 | c.199del p.A67Lfs*6 (on ENST00000392278 / NM_001031726.3; = p.A56Lfs*6 on NM_031448.6) | Frame Shift Del (DEL) | VAF 31/99 reads (31%) | catalogued as rs398122409, CD129885, CD132613; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CSPP1 | c.2831del p.N944Mfs*2 (on ENST00000676605; = p.N903Mfs*2 on NM_024790.6) | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | catalogued as rs863225190, COSV51582895; ClinVar: pathogenic; called by mutect2, varscan2
- CYP11B1 | c.956C>T p.T319M | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs104894068, CM970407, COSV52827729; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNMA1 | c.2026del p.Y676Tfs*15 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | catalogued as rs762705295; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 19/69 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRT5 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs61297109, CM045867, CM103083, CM930459, COSV52860636; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- MYH7 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs727503258, COSV100805719; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NOL4 | c.1267T>G p.L423V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs267605178, COSV52337695, COSV52338459, COSV52349574; called by muse, mutect2, varscan2
- STAT1 | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs587777630, CM125693, COSV63116411; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACACB | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.301); catalogued as rs144515904; called by muse, mutect2, varscan2
- ACOT7 | c.1091G>A p.R364Q (on ENST00000377855 / NM_181864.3; = p.R354Q on NM_007274.4) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs756883014, COSV100830313; called by muse, mutect2, varscan2
- ACSS2 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780837244, COSV53624749; called by muse, mutect2, varscan2
- ACTN2 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs761640231, COSV63977686; called by muse, mutect2, varscan2
- ADAD2 | c.953C>T p.A318V (on ENST00000315906 / NM_001145400.2; = p.A400V on NM_139174.4) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.334); catalogued as COSV99235736; called by muse, mutect2, varscan2
- ADAM23 | c.2340dup p.K781Qfs*3 | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | catalogued as rs767549806; called by mutect2, varscan2
- ADAM7 | c.2089A>C p.K697Q | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as COSV99445101; called by muse, mutect2, varscan2
- ADAMTS12 | c.2302G>A p.A768T | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100710660; called by muse, mutect2, varscan2
- ADAMTS16 | c.2227T>A p.S743T | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV56982957, COSV57000682, COSV99943085; called by muse, mutect2, varscan2
- ADAMTS20 | c.982A>G p.T328A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as rs759824392, COSV101240395; called by muse, mutect2
- ADCY2 | c.1414A>G p.S472G | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100604181; called by muse, mutect2, varscan2
- ADGRF4 | c.245del p.K82Sfs*29 | Frame Shift Del (DEL) | VAF 19/84 reads (23%) | catalogued as rs764604854; called by mutect2, pindel, varscan2
- ADGRG4 | c.8492C>T p.A2831V | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99796854; called by muse, mutect2, varscan2
- ADGRL3 | c.1534C>A p.L512I (on ENST00000506720 / NM_001322402.2; = p.L444I on NM_015236.6) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as COSV101547401, COSV72231589; called by muse, mutect2, varscan2
- AFDN | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | catalogued as COSV100653566; called by muse, mutect2, varscan2
- AHNAK | c.2569G>A p.A857T | Missense Mutation (SNP) | VAF 76/290 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as rs773932572, COSV99949683; called by muse, mutect2, varscan2
- AHNAK2 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as rs374238837, COSV60913733; called by muse, mutect2, varscan2
- ALAS2 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs752853849, COSV58188274, COSV58190561; called by muse, mutect2, varscan2
- AMER1 | c.158A>G p.K53R | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV100367076; called by muse, mutect2, varscan2
- ANGPT1 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as COSV52431619, COSV99864298; called by muse, mutect2, varscan2
- ANKRD12 | c.4075C>T p.L1359F | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); catalogued as COSV100042136; called by muse, mutect2, varscan2
- ANKRD27 | c.131C>A p.S44* | Nonsense Mutation (SNP) | VAF 72/197 reads (37%) | catalogued as COSV100043176; called by muse, mutect2, varscan2
- ANO3 | c.1882C>G p.R628G | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56784342, COSV99885817; called by muse, mutect2, varscan2
- ANO9 | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764201726, COSV100241215; called by muse, mutect2, varscan2
- APCDD1 | c.1297G>T p.G433W | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100789977, COSV100790017; called by muse, mutect2, varscan2
- AREG | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 99/326 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs747434597, COSV52644992; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 59/114 reads (52%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARHGAP29 | c.2980C>T p.P994S | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs1270802769, COSV99559065; called by muse, mutect2, varscan2
- ARHGEF4 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100388721; called by muse, mutect2, varscan2
- ARID1A | c.1804G>T p.E602* | Nonsense Mutation (SNP) | VAF 24/75 reads (32%) | catalogued as COSV100253681, COSV61382958; called by muse, mutect2, varscan2
- ARL15 | c.41A>T p.D14V | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.031); catalogued as COSV101544868; called by muse, varscan2
- ARRDC2 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99716969; called by muse, mutect2, varscan2
- ATG2A | c.5699C>T p.P1900L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100815545; called by muse, mutect2, varscan2
- ATP1A1 | c.1640del p.G547Afs*7 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs760784617; called by mutect2, pindel, varscan2
- ATP8A2 | c.1013G>A p.W338* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99684377; called by muse, mutect2, varscan2
- ATP8B2 | c.3607C>T p.R1203C (on ENST00000672630; = p.R1170C on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.764); catalogued as rs367887345; called by muse, mutect2, varscan2
- ATP8B3 | c.2995T>C p.Y999H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV100034980; called by muse, mutect2, varscan2
- ATPAF1 | c.919A>G p.I307V (on ENST00000574428; = p.I330V on NM_022745.4) | Missense Mutation (SNP) | VAF 77/226 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.309); catalogued as COSV100236330; called by muse, mutect2, varscan2
- ATRX | c.7076A>G p.K2359R | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV64874187, COSV64874943; called by muse, mutect2, varscan2
- BATF2 | c.545G>A p.G182D | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV100101902; called by muse, varscan2
- BDH1 | c.685del p.L229Wfs*3 | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | catalogued as rs1002260866; called by mutect2, pindel
- BEST3 | c.1332dup p.R445Qfs*58 | Frame Shift Ins (INS) | VAF 24/64 reads (38%) | catalogued as rs779566914; called by mutect2, varscan2
- BNC1 | c.1243A>G p.M415V | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs753399637, COSV100597495; called by muse, mutect2, varscan2
- BOC | c.2492C>T p.P831L | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1353827828, COSV99849404; called by muse, mutect2, varscan2
- BRINP2 | c.692C>A p.P231H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100838303, COSV64177289; called by muse, mutect2, varscan2
- BRPF3 | c.1281G>T p.E427D | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV100326194; called by muse, mutect2, varscan2
- BSCL2 | c.86T>A p.L29Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99582995; called by muse, mutect2, varscan2
- BTBD7 | c.728A>G p.Y243C | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.657); catalogued as COSV100108227; called by muse, mutect2, varscan2
- C12orf56 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1422577952, COSV100399857; called by muse, mutect2, varscan2
- C16orf92 | c.356T>G p.L119R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99662599; called by muse, mutect2, varscan2
- C3 | c.2728G>A p.V910M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV99837275; called by muse, mutect2, varscan2
- C3orf20 | c.2117A>C p.D706A | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1474815138, COSV99514580; called by muse, mutect2, varscan2
- C6orf58 | c.296G>T p.R99M | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as rs149295016, COSV100315062; called by muse, mutect2, varscan2
- C8A | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100776670; called by muse, mutect2
- CAPN1 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs762252249, COSV54201650; called by muse, mutect2, varscan2
- CCAR2 | c.1994G>A p.G665E | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.522); catalogued as rs201118681, COSV99374330; called by muse, mutect2, varscan2
- CCDC124 | c.604_606del p.K202del | In Frame Del (DEL) | VAF 7/22 reads (32%) | catalogued as rs756106175; called by pindel, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | catalogued as rs751135235; called by mutect2, varscan2
- CD2AP | c.1503G>T p.L501F | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV100830662; called by muse, mutect2, varscan2
- CD300A | c.662A>C p.K221T | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100177996; called by muse, mutect2, varscan2
- CDC42BPA | c.3349G>A p.D1117N (on ENST00000334218 / NM_001366019.2; = p.D1104N on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs751330332, COSV100506936; called by muse, mutect2, varscan2
- CDC42EP4 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201845163, COSV59964142; called by muse, mutect2, varscan2
- CDH3 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs757633932, COSV99869218; called by muse, mutect2, varscan2
- CDK2AP2 | c.151T>G p.F51V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV100039477; called by muse, mutect2, varscan2
- CEP192 | c.3397G>C p.D1133H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100382165; called by muse, mutect2, varscan2
- CEP57 | c.785del p.K262Rfs*31 | Frame Shift Del (DEL) | VAF 23/66 reads (35%) | catalogued as rs762013265, COSV57689966; called by mutect2, varscan2
- CFAP300 | c.275A>G p.E92G | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as COSV101462492; called by muse, mutect2, varscan2
- CFAP46 | c.6188C>T p.A2063V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV54150942, COSV99585612; called by mutect2, varscan2
- CFAP53 | c.1068G>T p.Q356H | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.214); catalogued as COSV101275029, COSV101275036; called by muse, mutect2, varscan2
- CFH | c.3140_3142del p.S1047del | In Frame Del (DEL) | VAF 26/81 reads (32%) | catalogued as rs1180820411; called by pindel, varscan2
- CGAS | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370272118; called by muse, mutect2, varscan2
- CGRRF1 | c.320T>C p.L107S | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV99370596; called by muse, mutect2, varscan2
- CHD7 | c.6593G>T p.G2198V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV101418466; called by muse, mutect2, varscan2
- CHD9 | c.5686A>G p.R1896G | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV99529762; called by muse, mutect2, varscan2
- CHRNA1 | c.787G>A p.V263I (on ENST00000261007 / NM_001039523.3; = p.V238I on NM_000079.4) | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as rs1414800603, COSV53682794; called by muse, mutect2
- CHRNA6 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV99373427; called by muse, mutect2, varscan2
- CIZ1 | c.902A>G p.E301G | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV99477143; called by muse, mutect2, varscan2
- CLTCL1 | c.4784C>T p.A1595V (on ENST00000427926 / NM_007098.4; = p.A1538V on NM_001835.4) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.455); catalogued as COSV99311076; called by muse, mutect2, varscan2
- CMYA5 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs373527728; called by muse, mutect2, varscan2
- CNGA2 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756195328, COSV100323969; called by muse, varscan2
- CNTN3 | c.2441T>C p.L814P | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99726148; called by muse, mutect2, varscan2
- CNTN6 | c.424C>A p.L142I | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.263); catalogued as COSV100610157; called by muse, mutect2, varscan2
- CNTNAP4 | c.1466G>A p.G489D | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs1366189550, COSV100273440; called by muse, mutect2, varscan2
- CNTRL | c.6072A>G p.K2024= | Splice Region (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99443919; called by muse, mutect2, varscan2
- COL21A1 | c.2672C>A p.P891H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99780308; called by muse, mutect2, varscan2
- COL4A3 | c.779A>G p.E260G | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV101170540; called by muse, mutect2, varscan2
- COL4A5 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.116); catalogued as COSV57870005; called by muse, mutect2, varscan2
- COL6A2 | c.2881G>A p.A961T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV99385477; called by muse, mutect2, varscan2
- COPB2 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1352790979, COSV100300817; called by muse, mutect2, varscan2
- COQ6 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV99474194; called by muse, mutect2, varscan2
- CPLX3 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs144213956; called by muse, mutect2, varscan2
- CPT1C | c.1897G>A p.A633T | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99773688; called by muse, mutect2, varscan2
- CSE1L | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs746788725, COSV99522282; called by muse, mutect2, varscan2
- CSMD1 | c.6271C>T p.P2091S (on ENST00000520002; = p.P2090S on NM_033225.6) | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100153893; called by muse, mutect2, varscan2
- CSMD3 | c.2317G>T p.D773Y (on ENST00000297405 / NM_001363185.1; = p.D669Y on NM_052900.3) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1410319945, COSV52271822, COSV99848223; called by muse, mutect2, varscan2
- CSPG4 | c.305C>T p.T102M | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs376877916, COSV57900862; called by muse, mutect2, varscan2
- CTPS1 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs372743741; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP26A1 | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 75/223 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV99814969; called by muse, mutect2, varscan2
- DCAKD | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs527558018, COSV60832501; called by muse, mutect2, varscan2
- DCN | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as rs1230851111, COSV50006638; called by muse, mutect2, varscan2
- DCST2 | c.1564C>T p.R522W | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs4845403, COSV99792267; called by muse, mutect2, varscan2
- DHRS3 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as COSV100879691; called by muse, mutect2, varscan2
- DLG5 | c.1616G>A p.S539N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100967896; called by muse, mutect2, varscan2
- DLX2 | c.463C>A p.P155T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV52232687, COSV99308680; called by muse, mutect2, varscan2
- DMWD | c.1199A>C p.E400A | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV99353698; called by muse, mutect2, varscan2
- DNAH2 | c.6130-2A>G p.X2044_splice | Splice Site (SNP) | VAF 19/55 reads (35%) | catalogued as COSV101209595; called by muse, mutect2, varscan2
- DNAH2 | c.10889T>C p.M3630T | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770175228, COSV101209597; called by muse, mutect2, varscan2
- DNAH3 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs371453732; called by muse, mutect2, varscan2
- DOT1L | c.2648T>C p.I883T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV101288831; called by muse, mutect2, varscan2
- DPF2 | c.1117C>A p.L373M | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99361973; called by muse, mutect2, varscan2
- DPYD | c.2293G>A p.V765M | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.506); catalogued as COSV100929442; called by muse, mutect2, varscan2
- DUOXA1 | c.256T>C p.S86P | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV99973566; called by muse, mutect2, varscan2
- DYNC2H1 | c.7205T>G p.I2402S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100519793; called by muse, mutect2, varscan2
- EFHB | c.1216T>C p.Y406H | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.326); catalogued as COSV99860265; called by muse, mutect2, varscan2
- EGR4 | c.1601C>T p.T534I (on ENST00000545030; = p.T431I on NM_001965.4) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101474272; called by muse, mutect2, varscan2
- EHBP1 | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as COSV50427477, COSV99861047; called by muse, mutect2, varscan2
- EHBP1L1 | c.2365T>G p.L789V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1243861951, COSV100500035; called by muse, mutect2, varscan2
- EHMT1 | c.3584T>C p.V1195A | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV101135095; called by muse, mutect2, varscan2
- EIF5B | c.2675G>T p.G892V | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99178882; called by muse, mutect2, varscan2
- ELMO1 | c.1960T>G p.F654V | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60330777; called by muse, mutect2, varscan2
- EP300 | c.4453-2A>G p.X1485_splice | Splice Site (SNP) | VAF 15/58 reads (26%) | catalogued as COSV54333949, COSV54334797; called by muse, mutect2, varscan2
- EPHA4 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.914); catalogued as COSV99917529; called by muse, mutect2, varscan2
- EPHA6 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs879119988, COSV101065619; called by muse, mutect2, varscan2
- EPHA7 | c.1449+2T>G p.X483_splice | Splice Site (SNP) | VAF 34/80 reads (43%) | catalogued as COSV100994382; called by muse, mutect2, varscan2
- ERBB3 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.697); catalogued as COSV57248597; called by muse, mutect2, varscan2
- ERC2 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV99890237; called by muse, mutect2, varscan2
- ERF | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs755151370, COSV99724855; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | catalogued as rs775950025; called by mutect2, varscan2
- EXOC3L1 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1205484225, COSV99333968; called by muse, mutect2, varscan2
- EXTL3 | c.707G>A p.C236Y | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99594364; called by muse, mutect2, varscan2
- F10 | c.1035G>T p.E345D | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV100979348; called by muse, mutect2, varscan2
- F8A1 | c.1083A>T p.Q361H | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV100371841; called by muse, mutect2, varscan2
- FAM13C | c.1238T>C p.V413A | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV53247089; called by muse, mutect2, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs748967872; called by mutect2, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | catalogued as rs746983128; called by mutect2, varscan2
- FAR1 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100701665; called by muse, mutect2, varscan2
- FAT4 | c.2749G>T p.A917S | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs745840096, COSV101272853; called by muse, mutect2, varscan2
- FBXL7 | c.1444G>A p.V482I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1219818114, COSV61641181; called by muse, mutect2, varscan2
- FBXO3 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as rs926200281, COSV99682342; called by muse, mutect2, varscan2
- FBXO36 | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV99390967; called by muse, mutect2, varscan2
- FEN1 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs756180049, COSV99952974; called by muse, mutect2, varscan2
- FER1L6 | c.2959C>T p.P987S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101206212; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 23/86 reads (27%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FILIP1L | c.2247del p.K749Nfs*2 (on ENST00000354552 / NM_182909.3; = p.K509Nfs*2 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 39/115 reads (34%) | catalogued as COSV58769165; called by mutect2, varscan2
- FLNC | c.3679A>G p.T1227A | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV100368768; called by muse, mutect2, varscan2
- FMO3 | c.122G>T p.W41L | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1512334, COSV100882559; called by muse, mutect2, varscan2
- FN1 | c.3119G>A p.R1040K | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100118316; called by muse, mutect2, varscan2
- FOXG1 | c.571A>G p.M191V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as COSV100487084; called by muse, mutect2, varscan2
- FTSJ3 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1454005062, COSV100037461; called by muse, mutect2, varscan2
- FUS | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV54215136; called by muse, mutect2, varscan2
- GABBR1 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100590083; called by muse, mutect2, varscan2
- GABRE | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as rs61740527, COSV100944190, COSV100944387; called by muse, mutect2, varscan2
- GAL3ST2 | c.542G>A p.S181N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as rs1000152829, COSV99511168; called by muse, mutect2, varscan2
- GALNT2 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100795909; called by muse, mutect2, varscan2
- GAPVD1 | c.3263G>A p.R1088H (on ENST00000394104; = p.R1097H on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs775868907, COSV99783820; called by muse, mutect2, varscan2
- GBP5 | c.731del p.K244Sfs*13 | Frame Shift Del (DEL) | VAF 38/146 reads (26%) | catalogued as rs34148688; called by mutect2, pindel, varscan2
- GEN1 | c.130del p.M44* | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as rs748084139; called by mutect2, varscan2
- GFM1 | c.836T>C p.L279S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99963191; called by muse, mutect2, varscan2
- GGT5 | c.1108dup p.D370Gfs*143 | Frame Shift Ins (INS) | VAF 13/49 reads (27%) | catalogued as rs747658965; called by mutect2, pindel, varscan2
- GJA5 | c.703A>G p.R235G | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99605824; called by muse, mutect2, varscan2
- GLI3 | c.681G>A p.A227= | Splice Region (SNP) | VAF 8/43 reads (19%) | catalogued as rs752998397, COSV67894163; ClinVar: uncertain significance; called by muse, mutect2
- GMIP | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99179606; called by muse, mutect2, varscan2
- GNB3 | c.465_467del p.N156del | In Frame Del (DEL) | VAF 13/51 reads (25%) | catalogued as rs782200140; called by pindel, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GNG2 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.158); catalogued as COSV58918189, COSV58920640; called by muse, mutect2, varscan2
- GOLGA2 | c.2549G>A p.R850Q | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.063); catalogued as rs748293881, COSV100360351; called by muse, mutect2, varscan2
- GPR179 | c.3886G>A p.G1296R (on ENST00000621958; = p.G1295R on NM_001004334.4) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs754423775; called by muse, mutect2
- GPR4 | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 33/119 reads (28%) | catalogued as rs769312976, COSV100547217; called by muse, mutect2, varscan2
- GPRIN1 | c.171del p.R58Gfs*78 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | catalogued as rs765009644; called by mutect2, pindel, varscan2
- GRIN2B | c.2480C>A p.A827E | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101663194, COSV74205288; called by muse, mutect2, varscan2
- H1-5 | c.274A>C p.S92R | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV100138091; called by muse, mutect2, varscan2
- HDAC9 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs369824636, COSV67784572; called by muse, mutect2, varscan2
- HEATR6 | c.665A>C p.K222T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99482622; called by muse, mutect2, varscan2
- HECW2 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs1284621782, COSV53673584; called by muse, mutect2, varscan2
- HERC1 | c.7682C>T p.A2561V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as COSV101496929; called by muse, mutect2, varscan2
- HGF | c.1004A>G p.H335R | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99738573; called by muse, mutect2, varscan2
- HK3 | c.1538G>A p.R513Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs769496471, COSV99459427; called by muse, mutect2, varscan2
- HOXA2 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV56067784, COSV56068432; called by muse, mutect2
- IARS2 | c.1479+2T>C p.X493_splice | Splice Site (SNP) | VAF 24/66 reads (36%) | catalogued as COSV100228629; called by muse, mutect2, varscan2
- IGHM | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.691); catalogued as rs781852051; called by muse, mutect2, varscan2
- IGKV1-27 | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1174531500; called by muse, mutect2, varscan2
- IGSF11 | c.866T>C p.L289P (on ENST00000393775 / NM_001015887.3; = p.L288P on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99062348; called by muse, mutect2, varscan2
- IGSF3 | c.616T>C p.S206P | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.029); catalogued as COSV100605120; called by muse, mutect2, varscan2
- INSR | c.4001A>G p.H1334R | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.084); catalogued as COSV100253586; called by muse, mutect2, varscan2
- IPO5 | c.353G>T p.R118M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99847690; called by muse, mutect2, varscan2
- IQGAP1 | c.1901T>C p.V634A | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV99185372; called by muse, mutect2, varscan2
- KANK1 | c.3046A>C p.S1016R | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV100620104; called by muse, mutect2, varscan2
- KCNB2 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750665772, COSV73051163; called by muse, mutect2, varscan2
- KCNG2 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs371967916; called by muse, mutect2, varscan2
- KCNH1 | c.2304G>C p.K768N (on ENST00000271751 / NM_172362.3; = p.K741N on NM_002238.4) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV55093668, COSV99661578; called by muse, mutect2, varscan2
- KCNH7 | c.2410A>C p.K804Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV100149887; called by muse, mutect2, varscan2
- KCNJ2 | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99696544; called by muse, mutect2, varscan2
- KCNQ3 | c.2339G>A p.R780H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); catalogued as rs747235713, COSV101196071; called by muse, mutect2, varscan2
- KCTD8 | c.463T>C p.S155P | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.972); catalogued as COSV100760131; called by muse, mutect2, varscan2
- KDM6A | c.3336_3338dup p.V1113dup | In Frame Ins (INS) | VAF 10/53 reads (19%) | catalogued as rs754641067; called by mutect2, pindel
- KIAA1109 | c.12688A>G p.S4230G | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99176568; called by muse, mutect2, varscan2
- KIAA1549L | c.392C>T p.A131V (on ENST00000321505; = p.A428V on NM_012194.3) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs1479202366, COSV99684501; called by muse, mutect2, varscan2
- KIAA1958 | c.1165A>G p.I389V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV100516488; called by muse, mutect2, varscan2
- KIF5B | c.1894T>C p.C632R | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs1420801636, COSV100192401; called by muse, mutect2, varscan2
- KIF6 | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV54699301, COSV99760797; called by muse, mutect2, varscan2
- KIF7 | c.3760del p.L1254Sfs*22 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | catalogued as rs747131428; called by mutect2, pindel, varscan2
- KIF7 | c.1652T>C p.L551P | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV101067977; called by muse, mutect2, varscan2
- KLHDC10 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV59053231; called by muse, mutect2, varscan2
- KMT2B | c.4708G>A p.A1570T | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99720679; called by muse, mutect2, varscan2
- KMT2C | c.1124T>G p.V375G | Missense Mutation (SNP) | VAF 26/736 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as COSV51507688; called by muse, mutect2
- KPRP | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100908806; called by muse, mutect2, varscan2
- KPRP | c.1540G>T p.G514C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100908807; called by muse, mutect2, varscan2
- L3MBTL4 | c.1660T>C p.S554P | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99531247; called by muse, mutect2, varscan2
- LAMA2 | c.7003G>A p.E2335K | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as rs908238310, COSV70355647; called by muse, mutect2, varscan2
- LARP7 | c.77del p.K26Rfs*36 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | catalogued as rs781724052; called by mutect2, pindel, varscan2
- LEXM | c.847del p.S283Lfs*51 | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | catalogued as COSV64023666; called by mutect2, pindel, varscan2
- LGI3 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs138233100; called by muse, mutect2, varscan2
- LLGL1 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV100375678; called by muse, mutect2
- LMO7 | c.875C>T p.A292V (on ENST00000357063; = p.A307V on NM_005358.5) | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs375314137; called by muse, mutect2, varscan2
- LMX1A | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as rs778377042, COSV54218498, COSV54225933; called by muse, mutect2, varscan2
- LPO | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs773286393, COSV51861746; called by muse, mutect2, varscan2
- LRAT | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV100312203; called by muse, mutect2, varscan2
- LRCH3 | c.2020C>G p.L674V | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1481276099, COSV58394894; called by muse, mutect2, varscan2
- LRP1 | c.1681C>A p.P561T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99677277; called by muse, mutect2, varscan2
- LRP1B | c.1154A>T p.Y385F | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101261338; called by muse, mutect2, varscan2
- LRRC32 | c.46C>A p.L16M | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV99477367; called by muse, mutect2, varscan2
- LRRTM1 | c.1272G>C p.Q424H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.535); catalogued as rs752164655, COSV99703226; called by muse, mutect2, varscan2
- LTBP1 | c.2842G>A p.A948T (on ENST00000404816 / NM_206943.4; = p.A622T on NM_000627.4) | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.673); catalogued as COSV100617952; called by muse, mutect2, varscan2
- MAG | c.97T>C p.F33L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as COSV100728064; called by muse, mutect2, varscan2
- MAGEE2 | c.133del p.Q45Sfs*27 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as rs1159257962; called by mutect2, pindel, varscan2
- MAK16 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 29/96 reads (30%) | catalogued as COSV100789442, COSV64078462; called by muse, mutect2, varscan2
- MAP2 | c.4420dup p.T1474Nfs*22 | Frame Shift Ins (INS) | VAF 13/64 reads (20%) | catalogued as rs1476495251; called by mutect2, varscan2
- MAP3K15 | c.2533G>A p.A845T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1417043774, COSV100135769; called by muse, mutect2, varscan2
- MCTP1 | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs1197773929, COSV100388218; called by muse, mutect2, varscan2
- MED16 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs547125995, COSV99516314; called by muse, varscan2
- MEGF11 | c.2516G>A p.S839N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV99989230; called by muse, mutect2, varscan2
- MEGF9 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.11); catalogued as COSV100879540; called by muse, mutect2, varscan2
- MFSD14B | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.077); catalogued as rs753330733, COSV100942811; called by muse, mutect2
- MGA | c.7397G>A p.R2466Q (on ENST00000219905 / NM_001164273.1; = p.R2257Q on NM_001080541.2) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs769953503, COSV54959556, COSV99581625; called by muse, mutect2, varscan2
- MICU3 | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as rs201988057, COSV100536600; called by muse, mutect2, varscan2
- MOGAT2 | c.476-2A>C p.X159_splice | Splice Site (SNP) | VAF 43/74 reads (58%) | catalogued as COSV99549771; called by muse, mutect2, varscan2
- MON1B | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.02); catalogued as rs376857114; called by muse, mutect2, varscan2
- MSANTD4 | c.561del p.F187Lfs*19 | Frame Shift Del (DEL) | VAF 32/116 reads (28%) | catalogued as rs1475601536; called by mutect2, pindel, varscan2
- MUC17 | c.373A>G p.S125G | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV100075107; called by muse, mutect2, varscan2
- MUC17 | c.4894C>G p.L1632V | Missense Mutation (SNP) | VAF 125/355 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100075111; called by muse, mutect2, varscan2
- MYO18A | c.5414A>G p.E1805G | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV100572755; called by muse, mutect2, varscan2
- MYOM1 | c.1187dup p.Y397Ifs*8 | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | catalogued as rs907635394; called by mutect2, pindel, varscan2
- NAALADL1 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs374691634; called by muse, mutect2, varscan2
- NBAS | c.1141del p.I381Sfs*10 | Frame Shift Del (DEL) | VAF 19/46 reads (41%) | catalogued as rs772472509; called by mutect2, varscan2
- NCAM1 | c.1275C>A p.Y425* (on ENST00000316851 / NM_181351.5; = p.Y415* on NM_000615.7) | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100378613; called by muse, varscan2
- NCKAP5 | c.5297C>T p.A1766V | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV100494478; called by muse, mutect2, varscan2
- NCKAP5 | c.1809C>A p.D603E | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.144); catalogued as rs201592269, COSV100494481; called by muse, mutect2, varscan2
- NCOA3 | c.1343T>C p.M448T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs1266846597, COSV100508280; called by muse, mutect2, varscan2
- NDRG1 | c.571G>T p.V191L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.057); catalogued as COSV100106490; called by muse, mutect2, varscan2
- NDUFA9 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.106); catalogued as rs199592341, CM1110249, COSV99865257, COSV99866170; called by muse, mutect2, varscan2
- NEBL | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0.019); catalogued as rs1237891829, COSV101009367, COSV65804899; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NELL2 | c.1037G>C p.R346T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV100420905; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 54/124 reads (44%) | catalogued as rs759081520; called by mutect2, varscan2
- NINL | c.1801G>A p.G601S | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs763077917, COSV99626353; called by muse, mutect2, varscan2
- NIT1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1163032160, COSV63502773; called by muse, mutect2, varscan2
- NME3 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754431274, COSV99169788; called by muse, mutect2, varscan2
- NOD1 | c.1117C>A p.R373S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as COSV104383669, COSV99768510; called by muse, mutect2, varscan2
- NOS1 | c.137T>G p.L46R | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100501449; called by muse, mutect2, varscan2
- NOS1AP | c.1241C>A p.P414H | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV100723638; called by muse, mutect2, varscan2
- NPAT | c.2506del p.S836Qfs*17 | Frame Shift Del (DEL) | VAF 15/88 reads (17%) | catalogued as rs757776966; called by mutect2, pindel, varscan2
- NR0B1 | c.200G>C p.C67S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV100973596; called by muse, mutect2, varscan2
- NR3C2 | c.924C>A p.C308* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as rs1553943033, COSV100679782; called by muse, mutect2, varscan2
- NRXN1 | c.4247T>G p.L1416R | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV100640746, COSV100640748; called by muse, mutect2, varscan2
- NRXN3 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100209291; called by muse, mutect2, varscan2
- NSMAF | c.1201del p.Y401Ifs*45 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as COSV50701027; called by pindel, varscan2
- NTHL1 | c.110G>A p.G37E (on ENST00000219066; = p.G29E on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1453838226, COSV99526528; called by mutect2, varscan2
- NUDT12 | c.208T>C p.C70R | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100048380; called by muse, mutect2, varscan2
- OBSCN | c.7003T>C p.Y2335H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.508); catalogued as COSV99484475; called by muse, mutect2, varscan2
- OBSCN | c.20977del p.A6993Pfs*79 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs762005098; called by mutect2, pindel, varscan2
- OCA2 | c.2078A>G p.E693G | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.2); catalogued as COSV100668705, COSV62344429; called by muse, mutect2, varscan2
- ODF4 | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.255); catalogued as COSV100071940; called by muse, mutect2, varscan2
- OLFML2B | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs759318997, COSV54200661; called by muse, mutect2, varscan2
- OR13C9 | c.497T>C p.L166S | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99403564; called by muse, mutect2, varscan2
- OR2G6 | c.667C>G p.Q223E | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV58574424, COSV58576188; called by muse, mutect2, varscan2
- OR4D6 | c.680C>A p.S227Y | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV100271843; called by muse, mutect2, varscan2
- OR4K2 | c.470T>C p.M157T | Missense Mutation (SNP) | VAF 68/438 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV100064771; called by muse, mutect2, varscan2
- OR52R1 | c.745T>C p.C249R | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100617810; called by muse, mutect2, varscan2
- OR6K2 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as rs141497361, COSV62744372; called by muse, mutect2, varscan2
- OSBPL1A | c.2378del p.N793Mfs*15 (on ENST00000319481 / NM_080597.4; = p.N280Mfs*15 on NM_018030.4) | Frame Shift Del (DEL) | VAF 50/136 reads (37%) | catalogued as rs751106039; called by mutect2, varscan2
- P3H3 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782398555, COSV51836821; called by mutect2, varscan2
- PAPPA2 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs548559188, COSV62787700; called by muse, mutect2, varscan2
- PCBP4 | c.1159G>A p.A387T (on ENST00000322099 / NM_033010.2; = p.A344T on NM_020418.4) | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.04); catalogued as COSV100437176; called by muse, mutect2, varscan2
- PCCA | c.2129_2130del p.V710Afs*23 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | catalogued as rs1317003529; called by pindel, varscan2
- PCDH15 | c.2823G>T p.K941N | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs773599066, COSV57395567, COSV57418006; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHB11 | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.643); catalogued as rs139788105, COSV100697185; called by muse, mutect2, varscan2
- PCDHB14 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53391746, COSV99505604; called by muse, mutect2, varscan2
- PCDHGA9 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.103); catalogued as rs377687399; called by muse, mutect2, varscan2
- PCIF1 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100976116; called by muse, mutect2, varscan2
- PDE4DIP | c.4123C>A p.L1375I | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100521900; called by muse, mutect2, varscan2
- PDIA5 | c.1157del p.P386Rfs*26 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | catalogued as rs766425459, COSV60251765; called by mutect2, pindel, varscan2
- PDK4 | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV99138991; called by muse, mutect2, varscan2
- PDPN | c.482+1G>A p.X161_splice (on ENST00000621990; = p.X237_splice on NM_006474.4) | Splice Site (SNP) | VAF 23/80 reads (29%) | catalogued as COSV99611829; called by muse, mutect2, varscan2
- PDS5B | c.1394C>A p.P465H | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100221552; called by muse, mutect2, varscan2
- PEAK1 | c.372A>C p.E124D | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs1225450519, COSV100433455; called by muse, mutect2, varscan2
- PEG3 | c.3823A>C p.S1275R | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.871); catalogued as COSV55629227, COSV55642916; called by muse, mutect2, varscan2
- PEX10 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs536486149, COSV99992234; ClinVar: uncertain significance; called by muse, varscan2
- PHEX | c.1683G>T p.W561C | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as CM092768, COSV101040043; called by muse, mutect2, varscan2
- PHF12 | c.1789A>G p.T597A | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99256255; called by muse, mutect2, varscan2
- PHF20L1 | c.513G>C p.W171C | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99622189; called by muse, mutect2
- PHRF1 | c.4567G>A p.A1523T (on ENST00000264555 / NM_001286581.2; = p.A1522T on NM_020901.4) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202209293; called by muse, mutect2, varscan2
- PI4K2A | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773047134, COSV65701109; called by muse, mutect2, varscan2
- PIK3AP1 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.08); catalogued as rs567912958, COSV59538318; called by muse, mutect2, varscan2
- PITPNM3 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.984); catalogued as rs201223846, COSV52599342; called by muse, mutect2, varscan2
- PIWIL2 | c.2393del p.K798Sfs*5 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | catalogued as COSV63249731; called by mutect2, pindel, varscan2
- PJA2 | c.344G>A p.S115N | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.076); catalogued as rs752706194, COSV100754547; called by muse, mutect2, varscan2
- PKD1 | c.7736G>A p.G2579D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.068); catalogued as COSV99239087; called by mutect2, varscan2
- PKHD1L1 | c.2980G>A p.G994R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199692519; called by muse, mutect2, varscan2
- PKN2 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777820496, COSV60135097; called by muse, mutect2, varscan2
- PLK1 | c.622A>G p.K208E | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100267491; called by muse, mutect2, varscan2
- POGLUT2 | c.1378T>A p.F460I | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV101050808, COSV101050823; called by muse, mutect2, varscan2
- POLR1A | c.2164C>T p.R722* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99808458; called by muse, mutect2, varscan2
- POP1 | c.2254del p.T752Lfs*12 | Frame Shift Del (DEL) | VAF 15/93 reads (16%) | catalogued as rs868622083, COSV62893071; called by mutect2, pindel, varscan2
- PPP1R1B | c.202A>G p.R68G | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99566368; called by muse, mutect2, varscan2
- PPP3CA | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | catalogued as COSV100548062; called by muse, mutect2, varscan2
- PPRC1 | c.4382del p.P1461Hfs*79 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as COSV53386648; called by mutect2, pindel, varscan2
- PRKACB | c.145del p.T49Pfs*13 | Frame Shift Del (DEL) | VAF 31/90 reads (34%) | catalogued as rs1291568884; called by mutect2, pindel, varscan2
- PRKCA | c.2019A>G p.*673Wext*20 | Nonstop Mutation (SNP) | VAF 30/92 reads (33%) | catalogued as COSV101373053; called by muse, mutect2, varscan2
- PRX | c.3709G>A p.A1237T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as COSV99397091; called by muse, mutect2, varscan2
- PTTG1IP | c.277+2T>C p.X93_splice | Splice Site (SNP) | VAF 11/46 reads (24%) | catalogued as COSV100445978; called by muse, mutect2, varscan2
- RABL6 | c.1453G>T p.A485S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.066); catalogued as COSV100273759; called by muse, mutect2
- RASGRP3 | c.1739C>T p.T580I (on ENST00000402538 / NM_001349975.2; = p.T579I on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV101274906; called by muse, mutect2, varscan2
- RAVER1 | c.1071del p.K358Sfs*177 (on ENST00000615032; = p.K358Sfs*149 on NM_133452.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 4/15 reads (27%) | catalogued as rs773370779, COSV99532335; called by mutect2, varscan2
- RBBP8 | c.1071del p.K357Nfs*3 | Frame Shift Del (DEL) | VAF 26/73 reads (36%) | catalogued as rs754547584, COSV59093143; ClinVar: uncertain significance; called by mutect2, varscan2
- RBM12 | c.1350del p.F450Lfs*13 | Frame Shift Del (DEL) | VAF 32/118 reads (27%) | catalogued as COSV58290226; called by mutect2, pindel, varscan2
- RBM41 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 39/124 reads (31%) | catalogued as COSV52564766; called by muse, mutect2, varscan2
- RBMS2 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.139); catalogued as COSV100008697; called by muse, mutect2, varscan2
- RBP3 | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs375761633; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RCOR3 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 19/66 reads (29%) | catalogued as COSV100879706; called by muse, mutect2, varscan2
- RDH5 | c.789G>T p.K263N | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.614); catalogued as COSV99141882; called by muse, mutect2, varscan2
- REEP1 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs777245164, COSV99382520; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RIC3 | c.593T>C p.M198T (on ENST00000309737 / NM_001206671.4; = p.M197T on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100112375; called by muse, mutect2, varscan2
- RIC8B | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773118905, COSV62695853; called by muse, mutect2, varscan2
- RMDN3 | c.1156del p.T386Lfs*22 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs745408248; called by mutect2, varscan2
- RNASE12 | c.179A>G p.H60R | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV100250632; called by muse, mutect2, varscan2
- RNF213 | c.9860A>G p.Y3287C | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100301538; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 13/93 reads (14%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROS1 | c.2659G>T p.A887S | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.211); catalogued as COSV100877719; called by muse, mutect2, varscan2
- RPL6 | c.86A>G p.K29R | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1380698487, COSV52517328; called by muse, mutect2, varscan2
- RPS6KA2 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs757007952, COSV55817218; called by muse, mutect2, varscan2
- RRBP1 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.045); catalogued as rs745522355, COSV99854570; called by muse, mutect2, varscan2
- RTCA | c.875A>G p.D292G | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99560161; called by muse, mutect2, varscan2
- RTEL1 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs201555555, COSV58896001; called by muse, mutect2
- RXRA | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs368400425; called by muse, mutect2, varscan2
- SAMD1 | c.815A>G p.K272R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99513979; called by muse, mutect2
- SEC16A | c.3074G>A p.S1025N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV99260242; called by muse, mutect2
- SEPTIN3 | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99352396; called by muse, mutect2, varscan2
- SEZ6L | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 34/124 reads (27%) | catalogued as COSV50662461; called by muse, mutect2, varscan2
- SF3B4 | c.902T>C p.M301T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV99641435; called by muse, mutect2, varscan2
- SFI1 | c.3058C>T p.Q1020* (on ENST00000400288 / NM_001007467.3; = p.Q989* on NM_014775.4) | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99837408; called by muse, mutect2, varscan2
- SFTPB | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs1442866526, COSV100667314; called by muse, mutect2, varscan2
- SHB | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.241); catalogued as rs774985216, COSV66629494; called by muse, mutect2, varscan2
- SHB | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.956); catalogued as COSV100891090; called by muse, mutect2, varscan2
- SHF | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as rs1278840070, COSV99334851; called by muse, mutect2, varscan2
- SHPRH | c.3487C>T p.R1163* (on ENST00000275233 / NM_001042683.3; = p.R1172* on NM_173082.3) | Nonsense Mutation (SNP) | VAF 14/119 reads (12%) | catalogued as COSV51604591; called by muse, mutect2, varscan2
- SHROOM2 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as rs1217043914, COSV66608934; called by muse, mutect2, varscan2
- SKOR1 | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.731); catalogued as COSV100408637; called by muse, mutect2, varscan2
- SLC16A6 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.182); catalogued as rs781822235, COSV100517417; called by mutect2, varscan2
- SLC22A6 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 20/124 reads (16%) | catalogued as COSV100842936; called by muse, mutect2, varscan2
- SLC25A24 | c.570del p.K190Nfs*29 | Frame Shift Del (DEL) | VAF 34/92 reads (37%) | catalogued as rs763273320; called by mutect2, varscan2
- SLC36A1 | c.991T>C p.L331= | Splice Region (SNP) | VAF 50/119 reads (42%) | catalogued as COSV99695767; called by muse, mutect2, varscan2
- SLC45A3 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); catalogued as rs753484902, COSV100901344; called by muse, mutect2, varscan2
- SLC6A15 | c.409A>G p.S137G | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.472); catalogued as COSV99881546; called by muse, mutect2, varscan2
- SLC7A2 | c.504del p.F168Lfs*9 (on ENST00000494857 / NM_001370338.1; = p.F208Lfs*9 on NM_003046.6) | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | catalogued as rs780138939; called by mutect2, pindel, varscan2
- SLCO6A1 | c.212A>G p.K71R | Missense Mutation (SNP) | VAF 67/210 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV65813124; called by muse, mutect2, varscan2
- SLITRK1 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as COSV100999824, COSV101000073; called by muse, mutect2, varscan2
- SMARCA1 | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100946730; called by muse, mutect2, varscan2
- SMARCA2 | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 31/97 reads (32%) | catalogued as rs1225541640, COSV100571540; called by muse, mutect2, varscan2
- SMG7 | c.1774A>G p.K592E | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV100750583; called by muse, mutect2, varscan2
- SMPD4 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1436979898, COSV100302778; called by muse, mutect2, varscan2
- SNAPC1 | c.639dup p.D214* | Frame Shift Ins (INS) | VAF 20/56 reads (36%) | catalogued as rs778933382; called by mutect2, varscan2
- SORBS1 | c.3629G>A p.G1210D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.188); catalogued as rs1467379245, COSV99528951; called by muse, mutect2, varscan2
- SOWAHC | c.1225G>A p.G409S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV100454369; called by muse, mutect2, varscan2
- SPNS2 | c.433T>C p.S145P | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV100223840; called by muse, mutect2, varscan2
- SPSB4 | c.496G>T p.G166W | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100141768; called by muse, mutect2
- SRRM3 | c.1688G>A p.R563Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV100418907; called by muse, mutect2
- SSX7 | c.465C>T p.S155= | Splice Region (SNP) | VAF 55/161 reads (34%) | catalogued as rs782421121, COSV53339456; called by muse, mutect2, varscan2
- ST3GAL4 | c.949G>A p.A317T (on ENST00000392669 / NM_001254758.1; = p.A313T on NM_006278.3) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.902); catalogued as COSV99917708; called by muse, mutect2, varscan2
- STAB1 | c.5494C>T p.R1832W | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs368512919; called by muse, mutect2, varscan2
- STRC | c.5117C>T p.S1706F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV100294444, COSV55853015; called by mutect2, varscan2
- SUPT6H | c.4204A>G p.S1402G | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100112783; called by muse, mutect2
- SYCN | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV59212254; called by muse, mutect2
- SYCP3 | c.643del p.I215Lfs*2 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | catalogued as rs761136347, CD035010; called by mutect2, varscan2
- SYMPK | c.2465C>T p.T822M | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs767812215, COSV55613554; called by muse, mutect2, varscan2
- SYT17 | c.485A>G p.Y162C | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100810866; called by muse, mutect2, varscan2
- TAF4B | c.2312A>G p.K771R | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99301005; called by muse, mutect2, varscan2
- TASP1 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.506); catalogued as rs749925651, COSV61814581; called by muse, varscan2
- TBC1D12 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs373749349; called by muse, mutect2, varscan2
- TBC1D25 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as COSV100952240; called by muse, mutect2, varscan2
- TBX18 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63738208; called by muse, mutect2, varscan2
- TCP11L1 | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374576071; called by muse, mutect2, varscan2
- TENM3 | c.4283G>A p.R1428Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs200031135; called by muse, mutect2, varscan2
- TFAP2C | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV99571808; called by muse, mutect2
- TGFBI | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs771481298, COSV59350536; called by muse, mutect2, varscan2
- TMEM138 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs141029883; called by muse, mutect2, varscan2
- TMEM181 | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV100892668; called by muse, mutect2, varscan2
- TMEM63C | c.1183A>G p.I395V | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.439); catalogued as COSV100029810; called by muse, mutect2, varscan2
- TNK1 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.105); catalogued as rs115923812, COSV61172635; called by muse, mutect2, varscan2
- TNPO3 | c.2541dup p.Y848Lfs*8 | Frame Shift Ins (INS) | VAF 42/136 reads (31%) | catalogued as rs761308428; called by mutect2, varscan2
- TONSL | c.1601A>G p.H534R | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101340315, COSV68048424; called by muse, mutect2, varscan2
- TPO | c.2435C>T p.A812V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs752390603, COSV100222217, COSV100222438; called by muse, mutect2, varscan2
- TPR | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV99834511; called by muse, mutect2, varscan2
- TRAF3 | c.1584G>A p.M528I | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61025984; called by muse, mutect2, varscan2
- TREX1 | c.68G>A p.G23D (on ENST00000625293 / NM_033629.6; = p.G13D on NM_007248.5) | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56498141, COSV99604191; called by muse, mutect2, varscan2
- TRIM60 | c.970C>T p.R324* | Nonsense Mutation (SNP) | VAF 39/105 reads (37%) | catalogued as rs745816410, COSV61971836, COSV61971841; called by muse, mutect2, varscan2
- TRPS1 | c.1080C>G p.N360K (on ENST00000220888 / NM_001330599.2; = p.N373K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99634568; called by muse, mutect2, varscan2
- TSHZ2 | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 21/84 reads (25%) | catalogued as COSV100296794; called by muse, mutect2, varscan2
- TSR2 | c.509A>G p.D170G | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100911265; called by muse, mutect2, varscan2
- TSSK1B | c.1075del p.Q359Nfs*43 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | catalogued as rs747842861, COSV101181233; called by mutect2, pindel
- TTC13 | c.332A>T p.D111V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.202); catalogued as COSV100793038; called by muse, mutect2, varscan2
- TTC7B | c.2444C>T p.A815V | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as rs569549056, COSV60624250; called by muse, mutect2
- TTC7B | c.1918C>T p.R640* | Nonsense Mutation (SNP) | VAF 58/172 reads (34%) | catalogued as rs940086560, COSV60639292; called by muse, mutect2, varscan2
- TTC9C | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs749635226, COSV99584774; called by muse, mutect2, varscan2
- TTN | c.88175C>T p.A29392V (on ENST00000591111; = p.A21968V on NM_003319.4) | Missense Mutation (SNP) | VAF 53/180 reads (29%) | PolyPhen benign (0); catalogued as COSV100630704; called by muse, mutect2, varscan2
- TYW5 | c.78+2T>C p.X26_splice | Splice Site (SNP) | VAF 5/13 reads (38%) | catalogued as rs776599948, COSV99705345; called by muse, mutect2, varscan2
- UAP1L1 | c.737del p.G246Efs*107 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | catalogued as COSV64306351; called by mutect2, pindel, varscan2
- UBE2N | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs754903428, COSV58869608; called by muse, mutect2, varscan2
- UBR5 | c.5257C>T p.R1753C | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV55280612, COSV55300023; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | catalogued as rs767420916; called by mutect2, varscan2
- UQCRFS1 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.224); catalogued as rs148167893; called by muse, mutect2
- URI1 | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100369248; called by muse, mutect2, varscan2
- USH2A | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.231); catalogued as COSV100242951; called by muse, mutect2, varscan2
- USP26 | c.1044del p.F348Lfs*7 | Frame Shift Del (DEL) | VAF 30/97 reads (31%) | catalogued as CM077651, COSV63708747; called by mutect2, varscan2
- USP39 | c.689T>C p.I230T | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100084078; called by muse, mutect2, varscan2
- USP40 | c.2653G>A p.A885T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV99297197; called by muse, mutect2, varscan2
- USP47 | c.463G>T p.G155C (on ENST00000399455 / NM_001372095.1; = p.G67C on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV100359976; called by muse, mutect2
- WASL | c.20A>C p.Q7P | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs779588397, COSV56135437; called by muse, mutect2, varscan2
- WDPCP | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99706922; called by muse, mutect2, varscan2
- WDR26 | c.1720G>A p.D574N (on ENST00000414423 / NM_001379403.1; = p.D474N on NM_025160.7) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.589); catalogued as COSV99691554; called by muse, mutect2, varscan2
- WDR35 | c.1658G>A p.C553Y (on ENST00000345530 / NM_001006657.2; = p.C542Y on NM_020779.4) | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99853541; called by muse, mutect2
- WEE2 | c.284C>A p.P95Q | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs755662789, COSV101285270; called by muse, mutect2, varscan2
- XAF1 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs371250443; called by muse, mutect2, varscan2
- XDH | c.2863C>T p.H955Y | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.77); PolyPhen benign (0.035); catalogued as rs762858102, COSV101052475; called by muse, mutect2, varscan2
- XIAP | c.1085T>C p.L362P | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100848989; called by muse, mutect2, varscan2
- XIRP2 | c.1130G>A p.S377N (on ENST00000628543; = p.S552N on NM_152381.6) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as COSV99747642; called by muse, mutect2, varscan2
- Z83844.2 | c.613C>T p.H205Y | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs779076656, COSV100379377; called by muse, mutect2, varscan2
- ZFAT | c.2243-3del | Splice Region (DEL) | VAF 8/43 reads (19%) | catalogued as rs35184160; called by mutect2, pindel
- ZFAT | c.719C>A p.P240H | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100914959; called by muse, mutect2, varscan2
- ZFP37 | c.1616A>G p.H539R | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768402026, COSV100953343; called by muse, mutect2, varscan2
- ZFX | c.466G>A p.V156M | Missense Mutation (SNP) | VAF 58/190 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV100458136; called by muse, mutect2, varscan2
- ZNF208 | c.2287A>G p.T763A | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.68); catalogued as COSV68101075; called by muse, mutect2, varscan2
- ZNF319 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.074); catalogued as COSV54624528; called by muse, mutect2, varscan2
- ZNF326 | c.899del p.N300Tfs*41 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs770970244; called by mutect2, pindel, varscan2
- ZNF337 | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 18/203 reads (9%) | catalogued as rs1268520245, COSV53321408; called by muse, mutect2
- ZNF568 | c.1458G>T p.M486I | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.269); catalogued as COSV100451453, COSV61741357; called by muse, mutect2, varscan2
- ZNF609 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1009330244, COSV58585037; called by muse, mutect2, varscan2
- ZNF609 | c.1917A>C p.K639N | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100441842, COSV58583823; called by muse, mutect2, varscan2
- ZNF611 | c.1874A>G p.N625S | Missense Mutation (SNP) | VAF 92/288 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.699); catalogued as rs1568598707, COSV100160611; called by muse, mutect2, varscan2
- ZNF777 | c.2326C>T p.R776W | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99925398; called by muse, mutect2, varscan2
- ZNF792 | c.1700G>A p.C567Y | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV101289763; called by muse, mutect2, varscan2
- ABCA9 | c.69dup p.W24Mfs*33 | Frame Shift Ins (INS) | VAF 9/63 reads (14%) | called by mutect2, pindel, varscan2
- ACSS1 | c.1080dup p.E361* | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.16395del p.F5465Lfs*13 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- AFF1 | c.973del p.T325Qfs*3 | Frame Shift Del (DEL) | VAF 33/114 reads (29%) | called by mutect2, pindel, varscan2
- ANK2 | c.4212del p.F1404Lfs*28 | Frame Shift Del (DEL) | VAF 20/81 reads (25%) | called by mutect2, varscan2
- ANKRD11 | c.1893dup p.H632Tfs*2 | Frame Shift Ins (INS) | VAF 32/125 reads (26%) | called by mutect2, pindel, varscan2
- AP3B1 | c.2769del p.K923Nfs*4 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | called by mutect2, varscan2
- AP3B1 | c.1789del p.I597Yfs*3 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | called by mutect2, pindel, varscan2
- ARAF | c.763del p.R255Gfs*37 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- BCOR | c.4862del p.P1621Qfs*53 (on ENST00000378444 / NM_001123385.2; = p.P1587Qfs*53 on NM_017745.6) | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | called by mutect2, pindel, varscan2
- BSN | c.3314del p.P1105Rfs*5 | Frame Shift Del (DEL) | VAF 35/120 reads (29%) | called by mutect2, pindel, varscan2
- CCDC107 | c.602_603del p.T201Rfs*8 | Frame Shift Del (DEL) | VAF 28/112 reads (25%) | called by pindel, varscan2
- CEP170 | c.611del p.N204Tfs*11 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- CNTLN | c.456dup p.Q153Tfs*4 | Frame Shift Ins (INS) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- COBL | c.3282dup p.F1095Ifs*81 | Frame Shift Ins (INS) | VAF 35/112 reads (31%) | called by mutect2, pindel, varscan2
- COPG2 | c.2407A>G p.T803A | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- COPS4 | c.1035del p.G346Dfs*3 | Frame Shift Del (DEL) | VAF 26/89 reads (29%) | called by mutect2, pindel, varscan2
- DCX | c.981del p.K328Sfs*21 (on ENST00000636035 / NM_001195553.2; = p.K323Sfs*82 on NM_000555.3) | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | called by mutect2, pindel, varscan2
- DDC | c.1297del p.I433Sfs*98 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | called by mutect2, pindel, varscan2
- DDX52 | c.147dup p.G50Wfs*31 | Frame Shift Ins (INS) | VAF 23/90 reads (26%) | called by mutect2, pindel, varscan2
- DSCC1 | c.281dup p.I95Hfs*5 | Frame Shift Ins (INS) | VAF 15/87 reads (17%) | called by mutect2, pindel, varscan2
- EIF4G2 | c.1560_1561del p.K520Nfs*2 | Frame Shift Del (DEL) | VAF 14/71 reads (20%) | called by mutect2, pindel, varscan2
- ENTPD6 | c.271dup p.L91Pfs*17 | Frame Shift Ins (INS) | VAF 21/63 reads (33%) | called by mutect2, pindel, varscan2
- ERCC6 | c.2144dup p.Y716Ifs*44 | Frame Shift Ins (INS) | VAF 16/50 reads (32%) | called by mutect2, pindel, varscan2
- FOSL1 | c.544del p.D182Tfs*40 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- GLRX2 | c.472del p.S158Vfs*22 (on ENST00000367439 / NM_197962.3; = p.S159Vfs*22 on NM_016066.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | called by mutect2, varscan2
- GNS | c.335_337del p.N112del | In Frame Del (DEL) | VAF 44/158 reads (28%) | called by pindel, varscan2
- GPRC5C | c.247dup p.L83Pfs*7 (on ENST00000652232; = p.L38Pfs*7 on NM_018653.4) | Frame Shift Ins (INS) | VAF 20/62 reads (32%) | called by mutect2, pindel, varscan2
- HLA-B | c.626del p.P209Qfs*5 | Frame Shift Del (DEL) | VAF 29/139 reads (21%) | called by mutect2, pindel, varscan2
- IGKV1D-43 | c.33del p.L12Sfs*15 | Frame Shift Del (DEL) | VAF 20/122 reads (16%) | called by mutect2, pindel, varscan2
- INSR | c.1851_1854del p.D618Pfs*22 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- IQGAP1 | c.2822dup p.N941Kfs*2 | Frame Shift Ins (INS) | VAF 24/94 reads (26%) | called by mutect2, varscan2
- JARID2 | c.1272del p.R425Gfs*36 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | called by mutect2, pindel, varscan2
- JDP2 | c.64del p.L22* | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | called by mutect2, varscan2
- KANK4 | c.248del p.P83Lfs*43 | Frame Shift Del (DEL) | VAF 41/136 reads (30%) | called by mutect2, pindel, varscan2
- KMO | c.1259dup p.V421Gfs*65 | Frame Shift Ins (INS) | VAF 22/98 reads (22%) | called by mutect2, varscan2
- KMT2C | c.427del p.S143Vfs*3 | Frame Shift Del (DEL) | VAF 22/85 reads (26%) | called by mutect2, pindel, varscan2
- LAMA2 | c.5259dup p.V1754Sfs*13 | Frame Shift Ins (INS) | VAF 12/52 reads (23%) | called by mutect2, pindel, varscan2
- LRP1B | c.13101dup p.H4368Afs*6 | Frame Shift Ins (INS) | VAF 22/84 reads (26%) | called by mutect2, pindel, varscan2
- LYST | c.9773del p.L3258* | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- M6PR | c.621del p.F208Sfs*7 | Frame Shift Del (DEL) | VAF 22/91 reads (24%) | called by mutect2, pindel, varscan2
- MESP2 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- MIA3 | c.503del p.N168Tfs*15 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | called by mutect2, pindel, varscan2
- MICAL3 | c.3639del p.S1214Rfs*3 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | called by mutect2, pindel, varscan2
- MUC5B | c.3983dup p.V1329Gfs*31 | Frame Shift Ins (INS) | VAF 8/21 reads (38%) | called by mutect2, varscan2
- NADSYN1 | c.1207del p.Q403Rfs*11 | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | called by mutect2, pindel, varscan2
- NCOR1 | c.4695dup p.T1566Hfs*51 | Frame Shift Ins (INS) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- NDUFA10 | c.803del p.K268Rfs*3 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- NDUFAF6 | c.358dup p.T120Nfs*8 | Frame Shift Ins (INS) | VAF 19/91 reads (21%) | called by mutect2, varscan2
- NFASC | c.494del p.P165Rfs*12 (on ENST00000339876 / NM_001378329.1; = p.P159Rfs*12 on NM_015090.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 43/186 reads (23%) | called by mutect2, pindel, varscan2
- PARP14 | c.1411del p.M471* | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel
- PCDHB5 | c.1278del p.T427Hfs*4 | Frame Shift Del (DEL) | VAF 41/152 reads (27%) | called by mutect2, pindel, varscan2
- PHF20L1 | c.2554dup p.M852Nfs*9 | Frame Shift Ins (INS) | VAF 18/98 reads (18%) | called by mutect2, pindel, varscan2
- POLR1F | c.932del p.K311Rfs*15 | Frame Shift Del (DEL) | VAF 47/140 reads (34%) | called by mutect2, varscan2
- PTP4A1 | c.458_460del p.R153del | In Frame Del (DEL) | VAF 30/110 reads (27%) | called by pindel, varscan2
- ROBO2 | c.3870del p.K1290Nfs*20 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- RP1 | c.2377del p.R793Efs*55 | Frame Shift Del (DEL) | VAF 17/94 reads (18%) | called by mutect2, pindel, varscan2
- SLC4A11 | c.1977_1980dup p.A661Rfs*87 | Frame Shift Ins (INS) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- SMG5 | c.1315_1317del p.P439del | In Frame Del (DEL) | VAF 14/58 reads (24%) | called by pindel, varscan2
- SNUPN | c.664dup p.T222Nfs*4 | Frame Shift Ins (INS) | VAF 27/103 reads (26%) | called by mutect2, pindel, varscan2
- SOAT1 | c.1146del p.F382Lfs*69 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- SRCAP | c.8503del p.V2835* | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- TBC1D8B | c.873del p.F291Lfs*9 | Frame Shift Del (DEL) | VAF 42/147 reads (29%) | called by mutect2, pindel, varscan2
- TDRD3 | c.1360dup p.Y454Lfs*2 | Frame Shift Ins (INS) | VAF 22/56 reads (39%) | called by mutect2, pindel, varscan2
- TEAD2 | c.882_883del p.H295Cfs*18 | Frame Shift Del (DEL) | VAF 35/149 reads (23%) | called by mutect2, pindel, varscan2
- TEP1 | c.5887del p.A1963Lfs*16 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | called by mutect2, pindel, varscan2
- TRAV12-3 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- TRIM3 | c.1666dup p.W556Lfs*8 | Frame Shift Ins (INS) | VAF 21/74 reads (28%) | called by mutect2, pindel, varscan2
- TRIM46 | c.1363del p.H455Ifs*32 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- TUT4 | c.25del p.S9Vfs*21 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- UPB1 | c.530del p.L177Cfs*7 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | called by mutect2, pindel, varscan2
- UPF2 | c.200del p.K67Rfs*14 | Frame Shift Del (DEL) | VAF 40/135 reads (30%) | called by mutect2, pindel, varscan2
- WRAP73 | c.712del p.L238Wfs*16 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | called by mutect2, pindel, varscan2
- YY1 | c.690dup p.D231Rfs*3 | Frame Shift Ins (INS) | VAF 19/60 reads (32%) | called by mutect2, varscan2
- ZBTB21 | c.402del p.V135Cfs*3 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | called by mutect2, pindel, varscan2
- ZNF711 | c.1172dup p.F392Vfs*2 | Frame Shift Ins (INS) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- ZNF776 | c.366del p.K122Nfs*31 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, varscan2
- ABCC1 | c.4323C>A p.A1441= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100580366; called by muse, mutect2, varscan2
- ABL2 | c.3084C>T p.G1028= (on ENST00000502732 / NM_007314.4; = p.G1013= on NM_005158.5) | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as rs776713584, COSV61013884; called by muse, mutect2, varscan2
- AC092143.1 | c.1698G>A p.T566= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as rs778395569, COSV59249133; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACVR1B | c.1458G>A p.T486= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as rs776085590, COSV99231989; called by muse, mutect2, varscan2
- ADAMTS9 | c.4803G>A p.P1601= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as rs746991473, COSV99900256; called by muse, mutect2, varscan2
- ADARB2 | c.1668G>A p.T556= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs368268294; called by muse, mutect2, varscan2
- ADGRF4 | c.966A>G p.S322= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV99349047; called by muse, mutect2, varscan2
- ALMS1 | c.5091A>G p.P1697= | Silent (SNP) | VAF 39/135 reads (29%) | catalogued as COSV100043787; called by muse, mutect2, varscan2
- ALX4 | c.676C>T p.L226= | Silent (SNP) | VAF 56/208 reads (27%) | catalogued as rs749075893, COSV100241316; called by muse, mutect2, varscan2
- ANOS1 | c.138C>T p.R46= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs754851546, COSV99391468; called by muse, varscan2
- APBA2 | c.168C>T p.P56= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs367887200, COSV68789165; called by muse, mutect2, varscan2
- APBA2 | c.2199C>T p.P733= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs779082827, COSV99723612; called by muse, mutect2, varscan2
- AQP6 | c.322C>T p.L108= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100210284; called by muse, mutect2, varscan2
- ARSD | c.357C>T p.N119= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs201773531, COSV99471888; called by muse, mutect2, varscan2
- ATG14 | c.978C>T p.P326= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV99903042; called by muse, mutect2, varscan2
- BMP1 | c.2538G>A p.S846= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs763570635, COSV60528270; called by muse, mutect2, varscan2
- C15orf40 | c.186C>T p.C62= | Silent (SNP) | VAF 42/124 reads (34%) | catalogued as rs1264761052, COSV58449250; called by muse, mutect2, varscan2
- C20orf27 | c.492C>T p.D164= (on ENST00000379772 / NM_001258429.2; = p.D189= on NM_001039140.3) | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99422490; called by muse, mutect2, varscan2
- CACNA1C | c.579C>T p.N193= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs561224137, COSV59753151; ClinVar: benign / likely benign; called by muse, mutect2
- CACNG3 | c.552C>T p.F184= | Silent (SNP) | VAF 49/159 reads (31%) | catalogued as rs988067948, COSV99137171; called by muse, mutect2, varscan2
- CASKIN2 | c.2898C>T p.P966= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs981892810, COSV58600056; called by muse, mutect2
- CCDC39 | c.633A>G p.Q211= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV99870681; called by muse, mutect2, varscan2
- CCDC74B | c.966G>A p.T322= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs755279496, COSV100134202; called by muse, mutect2, varscan2
- CDC42EP4 | c.732C>T p.G244= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs779555869, COSV59961961; called by muse, mutect2, varscan2
- CDKN2A | c.219C>T p.A73= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs730881679, COSV58718388, COSV58729115; called by muse, mutect2
- CDYL2 | c.96C>T p.Y32= | Silent (SNP) | VAF 44/118 reads (37%) | catalogued as rs766832943, COSV101629629; called by muse, mutect2, varscan2
- CEP120 | c.1197A>G p.A399= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as COSV100071491; called by muse, mutect2, varscan2
- CLEC16A | c.622C>T p.L208= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs377250814, COSV101278494; called by muse, mutect2, varscan2
- CLPP | c.235C>T p.L79= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as rs1264248563, COSV99832253; called by muse, mutect2, varscan2
- CNTN6 | c.843C>T p.I281= | Silent (SNP) | VAF 44/118 reads (37%) | catalogued as COSV100611871; called by muse, mutect2, varscan2
- CRYGA | c.177C>T p.R59= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100378670; called by muse, mutect2, varscan2
- CSF1R | c.1521G>A p.T507= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs1232530105, COSV53828281, COSV99643172; called by muse, mutect2, varscan2
- DCAF12L1 | c.108G>A p.P36= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV64421575; called by muse, mutect2, varscan2
- DCX | c.537C>G p.P179= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV100576189, COSV100576766; called by muse, mutect2, varscan2
- DDX54 | c.2055G>A p.R685= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV100014216; called by muse, mutect2, varscan2
- DENND2B | c.324G>A p.A108= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as rs1274456052, COSV100567415; called by muse, mutect2, varscan2
- DLC1 | c.2712C>T p.P904= (on ENST00000276297 / NM_001348081.2; = p.P467= on NM_006094.5) | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs749152245, COSV52305385; called by muse, mutect2, varscan2
- DNAH11 | c.4425C>T p.Y1475= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as rs373706559; called by muse, mutect2, varscan2
- DNAH2 | c.9136C>T p.L3046= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV101209194, COSV101209596; called by muse, mutect2, varscan2
- DOCK3 | c.4272G>A p.T1424= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as rs375221528; called by muse, mutect2, varscan2
- EEF1A1 | c.210T>C p.G70= | Silent (SNP) | VAF 35/135 reads (26%) | catalogued as COSV58551050; called by muse, mutect2, varscan2
- ELFN2 | c.39C>T p.C13= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs746804136, COSV101297652; called by muse, varscan2
- EPX | c.1827T>C p.P609= | Silent (SNP) | VAF 12/141 reads (9%) | catalogued as COSV99836782; called by muse, mutect2
- ERLIN1 | c.93C>T p.G31= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as rs765656709, COSV100957276; called by muse, mutect2, varscan2
- FAM47C | c.519C>T p.D173= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100792325; called by muse, mutect2, varscan2
- FAT1 | c.10221G>A p.T3407= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs371432120; called by muse, mutect2, varscan2
- FBN1 | c.5163T>C p.C1721= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as COSV100356452; called by muse, mutect2, varscan2
- FBXO31 | c.1563G>A p.A521= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs550271598, COSV100291620; called by muse, mutect2, varscan2
- FRY | c.8697G>A p.T2899= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs1187006590, COSV100969941; called by muse, mutect2, varscan2
- FSCN3 | c.1266C>T p.C422= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV99757394; called by muse, mutect2, varscan2
- FZD2 | c.894C>T p.F298= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV59528293; called by muse, mutect2, varscan2
- GABARAPL2 | c.309A>C p.G103= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV99231190; called by muse, mutect2, varscan2
- GALE | c.207C>T p.D69= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as CM054733, COSV99354110; called by muse, mutect2, varscan2
- GDA | c.1002C>T p.G334= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV99429857; called by muse, mutect2, varscan2
- GDF2 | c.960C>T p.S320= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs782203502; called by muse, mutect2, varscan2
- GOLGA1 | c.1137C>A p.A379= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV101001996; called by muse, mutect2, varscan2
- GPR158 | c.354G>A p.A118= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as rs761268623, COSV66266040, COSV66273141; called by muse, mutect2, varscan2
- GPR17 | c.858C>T p.Y286= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs778001264, COSV99760775; called by muse, mutect2, varscan2
- GRHL1 | c.1053C>T p.I351= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs367582209; called by muse, mutect2, varscan2
- GRIK3 | c.1209G>A p.E403= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV66140409; called by muse, mutect2, varscan2
- HEXIM1 | c.840G>A p.Q280= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as rs761857124, COSV60177548; called by muse, mutect2, varscan2
- HIVEP1 | c.2652C>T p.N884= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as rs377061560; called by muse, mutect2, varscan2
- HS6ST2 | c.156G>A p.A52= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100897471; called by muse, varscan2
- HUS1B | c.519G>A p.A173= | Silent (SNP) | VAF 60/158 reads (38%) | catalogued as rs745661653, COSV100034248; called by muse, mutect2, varscan2
- IDS | c.66C>T p.V22= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs1469964896, COSV100558152; called by muse, mutect2, varscan2
- IFT20 | c.309G>A p.Q103= (on ENST00000395418 / NM_001267776.2; = p.A143T on NM_174887.4) | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as rs1433171735, COSV99880794; called by muse, mutect2, varscan2
- IGSF3 | c.3111C>T p.G1037= (on ENST00000369486 / NM_001007237.3; = p.G1057= on NM_001542.4) | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs373045635; called by muse, mutect2, varscan2
- IKBKB | c.1584C>T p.N528= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as rs202131707; ClinVar: likely benign; called by muse, mutect2, varscan2
- IMPG2 | c.3147C>A p.P1049= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV99516555; called by muse, mutect2, varscan2
- IQGAP3 | c.3762C>T p.C1254= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV63253268; called by muse, mutect2, varscan2
- ITIH6 | c.1641T>G p.G547= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99513993; called by muse, mutect2, varscan2
- JCAD | c.333C>T p.N111= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs778371105, COSV100948578; called by muse, mutect2
- JHY | c.1449G>A p.Q483= | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as COSV99913812; called by muse, mutect2, varscan2
- KAZN | c.129C>T p.G43= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV65721249; called by muse, mutect2, varscan2
- KCNB1 | c.1977T>C p.S659= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV100870596; called by muse, mutect2, varscan2
- KCNJ3 | c.570C>T p.R190= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV99715784; called by muse, mutect2, varscan2
- KHDC3L | c.567G>A p.S189= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs144624088, COSV64859397; called by muse, mutect2, varscan2
- KIAA0319 | c.1383T>C p.D461= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV100985820; called by muse, mutect2, varscan2
- KLHDC2 | c.819A>G p.L273= | Silent (SNP) | VAF 47/145 reads (32%) | catalogued as COSV100027142; called by muse, mutect2, varscan2
- LAMA5 | c.10698G>A p.T3566= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs557901425, COSV53366009; called by muse, mutect2, varscan2
- LDLR | c.564C>T p.Y188= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs121908034, CM920416; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- LGI3 | c.267G>A p.L89= | Silent (SNP) | VAF 23/143 reads (16%) | catalogued as COSV100103293; called by muse, mutect2, varscan2
- LHFPL3 | c.261C>T p.P87= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as rs758361986, COSV101308950; called by muse, mutect2, varscan2
- LMTK3 | c.3627A>G p.R1209= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as COSV99541239; called by muse, mutect2, varscan2
- LRFN1 | c.2130C>T p.Y710= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs757048407, COSV99953354; called by muse, mutect2, varscan2
- MAGEB6 | c.15C>T p.H5= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100983868; called by muse, mutect2, varscan2
- MAMLD1 | c.549C>T p.L183= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as rs781792398, COSV53382062; called by muse, mutect2, varscan2
- MARCO | c.66C>T p.H22= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV100503452; called by muse, mutect2
- MCHR1 | c.600C>A p.T200= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV50761685; called by muse, mutect2, varscan2
- MDGA2 | c.1411T>C p.L471= (on ENST00000399232 / NM_001113498.2; = p.L173= on NM_182830.4) | Silent (SNP) | VAF 47/131 reads (36%) | catalogued as COSV62098126; called by muse, mutect2, varscan2
- MEAK7 | c.765C>T p.N255= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs760675402, COSV59143145; called by muse, mutect2, varscan2
- MED16 | c.2565G>A p.P855= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs766876741, COSV54126728; called by muse, mutect2, varscan2
- MEIS3 | c.906G>A p.T302= (on ENST00000558555 / NM_001346148.1; = p.T348= on NM_020160.3) | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs781275325, COSV100520560; called by muse, mutect2, varscan2
- MEOX2 | c.906G>A p.A302= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as rs777058351, COSV56287124; called by muse, mutect2, varscan2
- MFAP3L | c.510C>A p.T170= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV100852715; called by muse, mutect2
- MFSD8 | c.1029A>G p.G343= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs1220404877, COSV99614699; called by muse, mutect2, varscan2
- MIA3 | c.5643G>A p.P1881= | Silent (SNP) | VAF 44/162 reads (27%) | catalogued as rs774619055, COSV60509657; called by muse, mutect2, varscan2
- MIS18A | c.465G>A p.T155= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs1240442881, COSV99267083; called by muse, mutect2, varscan2
- MSC | c.516C>T p.Y172= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs773546327, COSV57697426; called by muse, mutect2, varscan2
- MUL1 | c.597C>T p.G199= | Silent (SNP) | VAF 40/116 reads (34%) | catalogued as rs547802214, COSV51641929; called by muse, mutect2, varscan2
- MXRA8 | c.744T>C p.D248= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV100492116; called by muse, mutect2, varscan2
- MYPN | c.987G>A p.A329= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs199931312; called by muse, mutect2, varscan2
- NAPEPLD | c.27T>G p.S9= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV100440083; called by muse, mutect2, varscan2
- NARS1 | c.843T>C p.G281= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV99900745; called by muse, mutect2, varscan2
- NAT9 | c.579C>T p.H193= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs781337986, COSV99379830; called by muse, mutect2, varscan2
- NELFB | c.615C>T p.F205= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs182592368; called by muse, mutect2, varscan2
- NETO2 | c.537C>T p.F179= | Silent (SNP) | VAF 48/122 reads (39%) | catalogued as rs748318682, COSV57452236; called by muse, mutect2, varscan2
- NKAP | c.888A>T p.P296= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV101004299; called by muse, varscan2
- NKX6-2 | c.501C>T p.F167= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV63973770; called by muse, mutect2, varscan2
- NLRP8 | c.1053C>T p.L351= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as rs267605703, COSV52585055; called by muse, mutect2, varscan2
- NPC1L1 | c.570C>A p.G190= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV56926663, COSV99213540; called by muse, mutect2, varscan2
- OLIG3 | c.117G>A p.S39= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as rs762144975, COSV100880335; called by muse, mutect2, varscan2
- PARP3 | c.976C>T p.L326= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV99232378, COSV99232770; called by muse, mutect2, varscan2
- PCMTD1 | c.615T>C p.T205= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100859811; called by muse, mutect2, varscan2
- PFKFB2 | c.237T>C p.R79= | Silent (SNP) | VAF 83/310 reads (27%) | catalogued as COSV65548016; called by muse, mutect2, varscan2
- PHF20L1 | c.2772A>G p.V924= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV99622198; called by muse, mutect2, varscan2
- PLEKHA8 | c.1515C>T p.D505= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs755309982, COSV99322256; called by muse, mutect2, varscan2
- POLE | c.1711C>T p.L571= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV100268316; called by muse, mutect2, varscan2
- POU2F2 | c.420G>A p.P140= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs375042716; called by muse, mutect2, varscan2
- PPP6R3 | c.1362G>A p.R454= (on ENST00000393800 / NM_001352375.2; = p.R403= on NM_018312.5) | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs1234858015, COSV99677552; called by muse, mutect2, varscan2
- PTPN21 | c.1290C>T p.D430= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100162551; called by muse, mutect2, varscan2
- PTPRG | c.672C>T p.V224= | Silent (SNP) | VAF 48/167 reads (29%) | catalogued as rs753995594, COSV99876970; called by muse, mutect2, varscan2
- RAB17 | c.246C>T p.S82= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs377280711; called by muse, mutect2, varscan2
- RGS20 | c.207G>A p.P69= | Silent (SNP) | VAF 16/227 reads (7%) | catalogued as COSV52015381; called by muse, mutect2
- RGS21 | c.267C>T p.D89= | Silent (SNP) | VAF 38/110 reads (35%) | catalogued as COSV101314093; called by muse, mutect2, varscan2
- RGS6 | c.288A>G p.P96= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV100667026; called by muse, mutect2, varscan2
- RNF150 | c.417C>T p.N139= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100154173; called by muse, mutect2
- RNF168 | c.1396C>A p.R466= | Silent (SNP) | VAF 64/188 reads (34%) | catalogued as COSV100535128; called by muse, mutect2, varscan2
- ROR2 | c.1677C>T p.G559= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs768187491, COSV100996121; called by muse, mutect2, varscan2
- RUNX2 | c.333C>T p.A111= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV100767849; called by muse, mutect2, varscan2
- SAGE1 | c.231C>T p.V77= | Silent (SNP) | VAF 56/155 reads (36%) | catalogued as COSV100187956; called by muse, mutect2, varscan2
- SART3 | c.2196C>T p.S732= (on ENST00000228284; = p.S714= on NM_014706.4) | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs1356294877, COSV99934454; called by muse, mutect2, varscan2
- SBNO2 | c.3534C>T p.I1178= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100685041; called by muse, mutect2
- SH3TC2 | c.1941C>T p.G647= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100102375; called by muse, mutect2, varscan2
- SHMT1 | c.1248A>G p.K416= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100363681; called by muse, mutect2, varscan2
- SIDT1 | c.528C>T p.A176= | Silent (SNP) | VAF 55/206 reads (27%) | catalogued as COSV99334741; called by muse, mutect2, varscan2
- SLC25A41 | c.579C>T p.G193= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV100383160; called by muse, mutect2, varscan2
- SLC30A3 | c.333G>A p.A111= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs372422099, COSV51984941; called by muse, mutect2, varscan2
- SLC5A4 | c.186T>C p.G62= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV99832146; called by muse, mutect2, varscan2
- SLC7A14 | c.438C>T p.G146= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs1388380701, COSV99201030; called by muse, mutect2, varscan2
- SLC9A7 | c.2151A>C p.L717= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs771848854, COSV100092787; called by muse, mutect2, varscan2
- SON | c.2733T>G p.P911= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as COSV99279913; called by muse, mutect2, varscan2
- SORCS3 | c.1782C>A p.S594= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100865669; called by muse, varscan2
- SOX7 | c.723G>A p.P241= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs977038647, CM137511, COSV58730594; called by muse, mutect2, varscan2
- SP8 | c.576G>A p.S192= (on ENST00000361443 / NM_198956.4; = p.S210= on NM_182700.6) | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV63865978; called by muse, mutect2
- SRM | c.417C>T p.G139= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV100978969; called by muse, mutect2, varscan2
- TBCD | c.1932G>A p.T644= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1349702035, COSV62797928; called by muse, mutect2
- TDRD6 | c.2079G>A p.T693= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs377047426; called by muse, mutect2, varscan2
- TENM1 | c.4734G>A p.A1578= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as rs748565386, COSV100950980, COSV64436887; called by muse, mutect2, varscan2
- THADA | c.5697G>T p.V1899= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99144248; called by muse, mutect2, varscan2
- TJP1 | c.3504T>C p.H1168= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV100633187; called by muse, mutect2, varscan2
- TK1 | c.261G>A p.E87= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs1208438089, COSV100015107; called by muse, mutect2
- TNRC6B | c.648C>T p.T216= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as rs375524285; called by muse, mutect2, varscan2
- TPX2 | c.1131T>C p.R377= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as COSV100302105; called by muse, mutect2, varscan2
- TRBV29-1 | c.201C>A p.G67= | Silent (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.5490G>A p.G1830= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV99272803; called by muse, mutect2, varscan2
- TTN | c.29535G>A p.T9845= (on ENST00000591111; = p.T8918= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs1046922182, COSV100630706; called by muse, mutect2, varscan2
- UBN2 | c.3930A>C p.G1310= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV99944489; called by muse, mutect2, varscan2
- VIM | c.354C>T p.I118= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99813357; called by muse, mutect2, varscan2
- VIRMA | c.1258T>C p.L420= | Silent (SNP) | VAF 42/196 reads (21%) | catalogued as rs1194046376, COSV99889509; called by muse, mutect2, varscan2
- ZBTB1 | c.591C>T p.S197= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as rs376564161; called by muse, mutect2, varscan2
- ZBTB46 | c.957C>T p.T319= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs757726466, COSV99829711; called by muse, mutect2, varscan2
- ZNF445 | c.9A>G p.P3= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV101253886; called by muse, mutect2, varscan2
- ZNF565 | c.1104C>T p.I368= (on ENST00000355114; = p.I328= on NM_152477.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV100412003; called by muse, mutect2, varscan2
- ZNF57 | c.1239G>A p.T413= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as rs531302803, COSV100182916; called by muse, varscan2
- ZNF616 | c.1212T>C p.T404= | Silent (SNP) | VAF 78/244 reads (32%) | catalogued as rs775773375, COSV100348619; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840599 G>A | 5'Flank (SNP) | VAF 13/33 reads (39%) | catalogued as rs1209487203, COSV100007692; called by muse, mutect2, varscan2
- C7orf66 | n.316A>G | RNA (SNP) | VAF 37/120 reads (31%) | catalogued as rs781243164; called by muse, mutect2, varscan2
- CSDC2 | chr22:41577414 G>T | 3'Flank (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99348280; called by muse, mutect2, varscan2
- DUSP13 | c.*268C>T | 3'UTR (SNP) | VAF 35/119 reads (29%) | catalogued as rs1438092402, COSV100403846; called by muse, varscan2
- FAM153CP | chr5:178056121 C>A | 3'Flank (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- KCNAB1 | c.276-129568G>A | Intron (SNP) | VAF 14/50 reads (28%) | catalogued as COSV56744375; called by muse, mutect2, varscan2
- KIF16B | c.3498+3111del | Intron (DEL) | VAF 22/112 reads (20%) | called by mutect2, pindel, varscan2
- MACF1 | c.15832-11072del | Intron (DEL) | VAF 10/80 reads (13%) | called by mutect2, pindel, varscan2
- MIR1208 | chr8:128150186 ins G | RNA (INS) | VAF 13/52 reads (25%) | catalogued as rs745702657; called by mutect2, varscan2
- MMP19 | c.895+100A>G | Intron (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100491269; called by muse, mutect2, varscan2
- NCF4 | c.759-99A>G | Intron (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99957553; called by muse, mutect2, varscan2
- OR3A4P | n.1226G>A | RNA (SNP) | VAF 36/99 reads (36%) | called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1619A>G | RNA (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- PSEN2 | c.-20-1227G>A | Intron (SNP) | VAF 54/178 reads (30%) | catalogued as COSV100423312; called by muse, varscan2
- RMDN2 | c.452+21918del | Intron (DEL) | VAF 29/73 reads (40%) | catalogued as rs761706403; called by mutect2, varscan2
- RNF216 | c.202-34G>A | Intron (SNP) | VAF 46/171 reads (27%) | catalogued as COSV101111386; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23932G>T | Intron (SNP) | VAF 47/157 reads (30%) | catalogued as rs777620829, COSV101044999; called by muse, mutect2, varscan2
- SNORD114-24 | n.68T>C | RNA (SNP) | VAF 34/114 reads (30%) | called by muse, mutect2, varscan2
- SNORD116-21 | n.6G>A | RNA (SNP) | VAF 104/308 reads (34%) | catalogued as rs777585455; called by muse, mutect2, varscan2
- SREK1 | c.-264G>A | 5'UTR (SNP) | VAF 50/137 reads (36%) | catalogued as rs762917969, COSV52335330, COSV99398514; called by muse, mutect2, varscan2
- SYCE1 | chr10:133554681 C>A | 3'Flank (SNP) | VAF 14/26 reads (54%) | catalogued as rs989096842; called by muse, mutect2, varscan2
- ZSCAN32 | c.695-119T>C | Intron (SNP) | VAF 3/26 reads (12%) | catalogued as COSV100514585; called by muse, mutect2
